Surgical pathology report (de-identified scan), TCGA case TCGA-36-2544, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site BC Cancer Agency, specimen TCGA-36-2544-01A (Primary Tumor).

[page 1 of 3]
[REDACTED] CGA-36-2544

Surgical Pathology Consultation Report

Case Number:

Collect Date:

Receive Date:

Date Reported:

Patient's Name:

MRN:

PHN:

DOB/Gender:

Ordering
Physician:

Final Diagnosis:

A. Omentum: extensive involvement by high-grade serous carcinoma

B. Uterus (with cervix), tubes and ovaries:

1. bilateral ovarian involvement by high-grade serous carcinoma (see comment)

2. tumor extensively involves the serosal surfaces of both fallopian tubes and uterus, and the cul-de-sac

3. atrophic endometrium and benign leiomyomas

4. unremarkable cervix

C. Peritoneal washings ([REDACTED]): positive for serous carcinoma

Comment: Although both ovaries show surface involvement by tumour, they also show a degree of parenchymal involvement that exceeds that allowable by [REDACTED] for a primary peritoneal serous carcinoma, and thus the tumour would be classified as ovarian in origin.

Clinical History as Provided by Submitting Physician:

[REDACTED]
?Ovarian vs. primary peritoneal

[page 2 of 3]
- A. Omentum
- B. Uterus, ovaries, cervix and tubes

Specimens Received:

- A: Omentum
- B: uterus, ovaries, cervix and tubes

Gross Description:

The specimen is received in two containers both labelled with the patient's demographics.

Container A is labelled OMENTUM and consists of a piece of omental tissue measuring 35 x up to 24 x 5 cm. The omental tissue is mostly replaced by solid tumour. Serial sectioning through the specimen reveals a solid white homogeneous cut surface. Representative sections are submitted in A1 to A6.

Container B is labelled UTERUS, OVARIES AND TUBES and consists of a hysterectomy and bilateral salpingo-oophorectomy specimen weighing 218 g. The uterus measures 8.5 x 5.5 x 3.5 cm. The serosal surface of the uterus has multiple tumour deposits, mostly near both anterior and posterior uterine-cervical junction. There are also tumour deposits on the superior aspect of the serosal surface. The cervix is covered by smooth white mucosa. Bivalvating the uterus, it reveals unremarkable endometrial surface lining, and unremarkable myometrium measures up to 1.3 cm in thickness. Serial sectioning through the uterine wall reveals a small white whorled, well circumscribed nodule subserosally and the anterior wall. The rest of the myometrium is unremarkable.

Representative sections are submitted as follows:

- B1 -anterior cervix
- B2 -posterior cervix
- B3 -posterior cervix with the serosal tumours
- B4 -cul-de-sac
- B5-B6 -anterior endometrium
- B7-B8 -posterior endometrium
- B9 -superior serosal tumour deposits.

The right fallopian tube has also tumour deposits on the serosal surface. The tube measures 5 cm in length and up to 0.6 cm in diameter. The tumour deposit is mostly on the proximal half of the tube. The right ovary has multiple nodular tumours present on the surface. The ovary with the surface tumour measures 4 x 1.5 x 2 cm.

Representative sections are submitted as follows:

- B10-B11 -fallopian tube
- B12-B14 -right ovary.

The left fallopian tube measures 5.5 cm in length and up to 0.5 cm in diameter. There

[page 3 of 3]
are tumour deposits near the proximal end of the fallopian tube. The left ovary is replaced by a tumour mass measuring 5 x 6 x 3 cm.

Representative sections are submitted as follows:

B15-B16 -fallopian tube

B17-B20 -tumour mass.

Source: NCI Genomic Data Commons file ca191aa1-721a-4032-8fc9-1496ce2106fb (TCGA-36-2544.87F69148-D6FB-4B70-8404-C24B106B6195.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).